Somatic mutation profile of tumor specimen C3N-00577-02 (aliquot CPT0069160006) from CPTAC case C3N-00577, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 72.7 years (26,555 days).
Specimen C3N-00577-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2510dee8-84e3-4b43-a1e6-cb4bf7a78673.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00577-71 (Blood Derived Normal), aliquot CPT0069270002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7835c192-f7db-47a6-85ed-16d3d6ddf077

The open-access MAF lists 89 somatic variants for this specimen: 50 protein-altering or splice-affecting, 30 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 30, Frame Shift Del 5, Intron 5, Nonsense Mutation 3, Splice Site 3, 5'Flank 2, Frame Shift Ins 1, RNA 1, In Frame Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- USH2A | c.14020A>G p.R4674G | Missense Mutation (SNP) | VAF 24/286 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs80338904, CM071135; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- AFF4 | c.1859C>A p.S620Y | Missense Mutation (SNP) | VAF 36/279 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1208947343; called by muse, mutect2, varscan2
- AQP9 | c.480C>G p.N160K | Missense Mutation (SNP) | VAF 68/159 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); catalogued as COSV54967546; called by muse, mutect2, varscan2
- ARHGAP9 | c.423G>C p.R141S | Missense Mutation (SNP) | VAF 22/280 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as COSV100712545; called by muse, mutect2
- C10orf90 | c.442G>A p.G148S | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.844); catalogued as rs774093912; called by muse, mutect2, varscan2
- CNOT4 | c.821+1G>A p.X274_splice | Splice Site (SNP) | VAF 9/30 reads (30%) | catalogued as rs759685984, CS1212371, COSV59650961; called by muse, mutect2, varscan2
- DPH5 | c.557G>T p.R186L | Missense Mutation (SNP) | VAF 29/126 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.716); catalogued as COSV59859843, COSV59860468; called by muse, mutect2, varscan2
- DR1 | c.516T>A p.D172E | Missense Mutation (SNP) | VAF 78/265 reads (29%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as COSV64725888; called by muse, mutect2, varscan2
- ERBB4 | c.2779C>T p.R927* | Nonsense Mutation (SNP) | VAF 19/262 reads (7%) | catalogued as rs537458255, COSV61460348; called by muse, mutect2
- GABRB1 | c.1264G>A p.G422R | Missense Mutation (SNP) | VAF 30/196 reads (15%) | SIFT tolerated (0.69); PolyPhen benign (0.005); catalogued as rs748097369, COSV54984293; called by muse, mutect2, varscan2
- GDF10 | c.497C>T p.P166L | Missense Mutation (SNP) | VAF 29/154 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs782581244; called by muse, mutect2, varscan2
- MYO3B | c.706C>G p.L236V | Missense Mutation (SNP) | VAF 149/244 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs556789877; called by muse, mutect2, varscan2
- PCDHB6 | c.2150C>T p.A717V | Missense Mutation (SNP) | VAF 49/494 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.617); catalogued as rs1471552438, COSV50704040; called by muse, mutect2, varscan2
- AJM1 | c.2588C>T p.A863V | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- CAPRIN2 | c.1102_1104+20del p.X368_splice | Splice Site (DEL) | VAF 16/94 reads (17%) | called by mutect2, pindel
- CDIP1 | c.341C>T p.T114I | Missense Mutation (SNP) | VAF 64/490 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.559); called by muse, mutect2, varscan2
- COL22A1 | c.443del p.L148Rfs*81 | Frame Shift Del (DEL) | VAF 54/142 reads (38%) | called by mutect2, pindel, varscan2
- CPA5 | c.818A>G p.N273S | Missense Mutation (SNP) | VAF 48/187 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CRHR2 | c.619T>A p.C207S | Missense Mutation (SNP) | VAF 40/215 reads (19%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- DDR1 | c.2317_2320del p.V774Gfs*13 (on ENST00000324771; = p.V737Gfs*13 on NM_001954.4) | Frame Shift Del (DEL) | VAF 36/264 reads (14%) | called by mutect2, pindel, varscan2
- DRD4 | c.610C>T p.P204S | Missense Mutation (SNP) | VAF 176/409 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- EFNA1 | c.160T>C p.Y54H | Missense Mutation (SNP) | VAF 32/267 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EMC9 | c.415_420del p.R139_W140del | In Frame Del (DEL) | VAF 28/161 reads (17%) | called by mutect2, pindel, varscan2
- EPRS1 | c.1130_1131dup p.D378Mfs*7 | Frame Shift Ins (INS) | VAF 10/115 reads (9%) | called by mutect2, pindel
- GOLGA8J | c.115A>T p.N39Y | Missense Mutation (SNP) | VAF 82/283 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- GPD1 | c.17T>A p.V6D | Missense Mutation (SNP) | VAF 114/299 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- HSPG2 | c.7597G>T p.A2533S | Missense Mutation (SNP) | VAF 19/359 reads (5%) | SIFT tolerated (0.4); PolyPhen benign (0.042); called by muse, mutect2
- LYST | c.2530A>G p.I844V | Missense Mutation (SNP) | VAF 37/332 reads (11%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- MLLT10 | c.572G>A p.C191Y | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NCOA5 | c.443dup p.Y148* | Nonsense Mutation (INS) | VAF 73/249 reads (29%) | called by mutect2, pindel, varscan2
- OR2V1 | c.700G>T p.A234S | Missense Mutation (SNP) | VAF 29/147 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- OR5B17 | c.532G>A p.D178N | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- OTOP2 | c.458T>A p.F153Y | Missense Mutation (SNP) | VAF 58/343 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PBRM1 | c.4680+2T>C p.X1560_splice (on ENST00000296302 / NM_001366071.2; = p.X1453_splice on NM_018313.5) | Splice Site (SNP) | VAF 63/123 reads (51%) | called by muse, mutect2, varscan2
- RABGGTA | c.26C>A p.T9K | Missense Mutation (SNP) | VAF 36/192 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- RDH13 | c.386G>T p.R129L (on ENST00000415061 / NM_001145971.2; = p.R58L on NM_138412.4) | Missense Mutation (SNP) | VAF 95/273 reads (35%) | SIFT tolerated (0.72); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- RELN | c.8608C>T p.Q2870* | Nonsense Mutation (SNP) | VAF 45/203 reads (22%) | called by muse, mutect2, varscan2
- SHOX | c.766T>C p.S256P | Missense Mutation (SNP) | VAF 133/495 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- SLC22A7 | c.943A>G p.S315G (on ENST00000372585 / NM_153320.2; = p.S313G on NM_006672.3) | Missense Mutation (SNP) | VAF 54/196 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- SNAP91 | c.1748C>T p.A583V | Missense Mutation (SNP) | VAF 33/185 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TBX5 | c.212del p.G71Afs*4 | Frame Shift Del (DEL) | VAF 185/601 reads (31%) | called by mutect2, pindel, varscan2
- TECTA | c.2020C>A p.Q674K | Missense Mutation (SNP) | VAF 23/195 reads (12%) | SIFT tolerated (0.39); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- TIAM1 | c.2021G>T p.G674V | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- TLE3 | c.88_101delinsT p.K30Cfs*29 | Frame Shift Del (DEL) | VAF 74/176 reads (42%) | called by pindel, varscan2*
- TLN1 | c.4118T>C p.V1373A | Missense Mutation (SNP) | VAF 41/172 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- TRDN | c.397del p.I133* | Frame Shift Del (DEL) | VAF 3/23 reads (13%) | called by mutect2, pindel
- TRIM26 | c.1334C>A p.S445Y | Missense Mutation (SNP) | VAF 100/507 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- ZFR | c.83A>G p.Y28C | Missense Mutation (SNP) | VAF 77/286 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ZNF430 | c.1237T>C p.S413P | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ZNF470 | c.1189T>A p.F397I | Missense Mutation (SNP) | VAF 34/135 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- ANKRD39 | c.264T>G p.A88= | Silent (SNP) | VAF 253/504 reads (50%) | called by muse, mutect2, varscan2
- ATP6V1B1 | c.1482C>T p.I494= | Silent (SNP) | VAF 51/476 reads (11%) | called by muse, mutect2, varscan2
- CLUH | c.2169A>G p.S723= (on ENST00000435359; = p.S762= on NM_015229.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 57/194 reads (29%) | called by muse, mutect2, varscan2
- CUX1 | c.57A>G p.V19= (on ENST00000292535 / NM_181552.4; = p.V30= on NM_001913.5) | Silent (SNP) | VAF 58/279 reads (21%) | catalogued as rs1278377019; called by muse, mutect2, varscan2
- EP300 | c.3885T>C p.S1295= | Silent (SNP) | VAF 116/400 reads (29%) | called by muse, mutect2, varscan2
- KIR3DL3 | c.57C>T p.P19= | Silent (SNP) | VAF 17/57 reads (30%) | called by muse, mutect2, varscan2
- KMT2E | c.4833C>T p.P1611= | Silent (SNP) | VAF 67/380 reads (18%) | catalogued as rs1243172763; called by muse, mutect2, varscan2
- KRTAP4-9 | c.585C>G p.V195= | Silent (SNP) | VAF 43/311 reads (14%) | called by muse, mutect2, varscan2
- LRAT | c.615T>C p.S205= | Silent (SNP) | VAF 63/234 reads (27%) | called by muse, mutect2, varscan2
- MUC16 | c.11331C>G p.P3777= | Silent (SNP) | VAF 43/152 reads (28%) | catalogued as COSV67479511; called by muse, mutect2, varscan2
- OIT3 | c.312T>C p.A104= | Silent (SNP) | VAF 42/213 reads (20%) | called by muse, mutect2, varscan2
- OR9G4 | c.651C>T p.S217= | Silent (SNP) | VAF 37/347 reads (11%) | catalogued as rs147926428; called by muse, mutect2, varscan2
- OR9K2 | c.463C>T p.L155= (on ENST00000305377; = p.L133= on NM_001005243.1) | Silent (SNP) | VAF 56/290 reads (19%) | called by muse, mutect2, varscan2
- RGS20 | c.174G>A p.P58= | Silent (SNP) | VAF 67/174 reads (39%) | catalogued as COSV52020210; called by muse, mutect2, varscan2
- SETD1A | c.723C>A p.T241= | Silent (SNP) | VAF 144/507 reads (28%) | called by muse, mutect2, varscan2
- SIGLEC6 | c.316C>T p.L106= | Silent (SNP) | VAF 10/190 reads (5%) | called by muse, mutect2
- SIGLECL1 | c.180C>T p.T60= | Silent (SNP) | VAF 138/313 reads (44%) | called by muse, mutect2, varscan2
- SIN3A | c.300G>A p.Q100= | Silent (SNP) | VAF 60/344 reads (17%) | catalogued as COSV64582507; called by muse, mutect2, varscan2
- SLC35G3 | c.273C>T p.G91= | Silent (SNP) | VAF 36/895 reads (4%) | catalogued as rs1302168191; called by muse, mutect2
- SLC6A12 | c.780T>C p.L260= | Silent (SNP) | VAF 55/365 reads (15%) | called by muse, mutect2, varscan2
- TERT | c.3267C>T p.Y1089= | Silent (SNP) | VAF 65/564 reads (12%) | catalogued as rs759883263, COSV99716060; ClinVar: likely benign; called by muse, mutect2, varscan2
- TIMM44 | c.438G>A p.K146= | Silent (SNP) | VAF 168/449 reads (37%) | catalogued as COSV54494255; called by muse, mutect2, varscan2
- TNFRSF25 | c.882G>A p.P294= | Silent (SNP) | VAF 15/178 reads (8%) | catalogued as rs758622492, COSV61068174; called by muse, mutect2
- TTC34 | c.2356C>T p.L786= | Silent (SNP) | VAF 40/202 reads (20%) | called by muse, mutect2, varscan2
- TTC6 | c.820C>T p.L274= (on ENST00000267368; = p.L1640= on NM_001310135.3) | Silent (SNP) | VAF 26/161 reads (16%) | called by muse, mutect2, varscan2
- TTLL10 | c.1323A>G p.E441= (on ENST00000379289 / NM_001130045.2; = p.E368= on NM_153254.3) | Silent (SNP) | VAF 24/344 reads (7%) | catalogued as COSV64959720; called by muse, mutect2
- USP34 | c.7800C>A p.A2600= | Silent (SNP) | VAF 64/135 reads (47%) | called by muse, mutect2, varscan2
- WDR81 | c.1098G>C p.L366= | Silent (SNP) | VAF 29/80 reads (36%) | called by muse, mutect2, varscan2
- ZBED9 | c.2667C>G p.L889= | Silent (SNP) | VAF 13/224 reads (6%) | called by muse, mutect2
- ZNF721 | c.2469A>G p.K823= (on ENST00000338977; = p.K835= on NM_133474.4) | Silent (SNP) | VAF 20/107 reads (19%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65506110 A>G | 5'Flank (SNP) | VAF 10/22 reads (45%) | called by muse, varscan2
- COPZ2 | c.112-258C>T | Intron (SNP) | VAF 31/107 reads (29%) | called by muse, mutect2, varscan2
- GLRX | chr5:95823891 C>A | 5'Flank (SNP) | VAF 109/299 reads (36%) | catalogued as rs751794723; called by muse, mutect2, varscan2
- ILF3 | c.2059+856C>T | Intron (SNP) | VAF 11/65 reads (17%) | catalogued as rs766111474; called by muse, mutect2, varscan2
- LINC00602 | n.1069G>C | RNA (SNP) | VAF 28/135 reads (21%) | called by muse, mutect2, varscan2
- MADCAM1 | c.667+1225C>T | Intron (SNP) | VAF 64/342 reads (19%) | called by muse, mutect2, varscan2
- PELP1 | c.1068+53C>T | Intron (SNP) | VAF 177/625 reads (28%) | called by muse, mutect2, varscan2
- PIWIL1 | c.2469+17G>C | Intron (SNP) | VAF 75/196 reads (38%) | called by muse, mutect2, varscan2
- RPL38 | c.*15T>C | 3'UTR (SNP) | VAF 33/171 reads (19%) | catalogued as rs775963020; called by muse, mutect2, varscan2
